Surgical pathology report (de-identified scan), TCGA case TCGA-49-4514, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4514-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1) LYMPH NODE, STATION 5 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

2) LYMPH NODE, R11 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

3) LYMPH NODE, L8 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

4) LUNG, LEFT UPPER LOBE (LOBECTOMY):

SPECIMEN TYPE:

lobectomy

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file ae4757c0-2fa4-4229-ba75-240a856ec7e3 (TCGA-49-4514.1D1C3125-05A9-4939-A296-F98D8F977AB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).